Somatic mutation profile of tumor specimen ALCH-AER1-TTP1-A (aliquot ALCH-AER1-TTP1-A-4-0-D-A612-36) from ALCHEMIST case ALCH-AER1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.6 years (26,525 days).
Specimen ALCH-AER1-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 962f6427-07db-4cca-86dd-742f92efcf8d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AER1-NB1-A (Blood Derived Normal), aliquot ALCH-AER1-NB1-A-1-0-D-A612-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b0e8f15-ef47-47f3-9a62-2eede7bc1ff8

The open-access MAF lists 133 somatic variants for this specimen: 79 protein-altering or splice-affecting, 35 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 35, Intron 6, 3'UTR 5, 5'UTR 4, Nonsense Mutation 3, Splice Region 3, RNA 3, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 271/1437 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- BABAM2 | c.988G>A p.V330I | Missense Mutation (SNP) | VAF 124/427 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as rs776406129, COSV59631171; called by muse, mutect2, varscan2
- CBLN4 | c.414C>G p.N138K | Missense Mutation (SNP) | VAF 32/379 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as COSV50352665; called by muse, mutect2
- COL9A3 | c.369dup p.G124Rfs*44 | Frame Shift Ins (INS) | VAF 68/509 reads (13%) | catalogued as rs1218220070; called by mutect2, pindel, varscan2
- EML6 | c.5423T>C p.I1808T | Missense Mutation (SNP) | VAF 26/748 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1031077336; called by muse, mutect2
- FLRT1 | c.819G>C p.Q273H | Missense Mutation (SNP) | VAF 63/256 reads (25%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.994); catalogued as COSV55360296; called by muse, mutect2, varscan2
- GGA1 | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 88/253 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs772002859; called by muse, mutect2, varscan2
- HECTD4 | c.8745C>T p.D2915= | Splice Region (SNP) | VAF 30/360 reads (8%) | catalogued as rs367828286; called by muse, mutect2
- KL | c.2300C>G p.S767C | Missense Mutation (SNP) | VAF 169/705 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV66308041; called by muse, mutect2, varscan2
- KMT2B | c.5954G>A p.G1985E | Missense Mutation (SNP) | VAF 34/323 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.07); catalogued as COSV55858080; called by muse, mutect2, varscan2
- KMT2D | c.13465G>A p.G4489R | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs200574556; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MANF | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 40/232 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1553621156; called by muse, varscan2
- MSL3 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 42/463 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as rs191141351, COSV56493475; called by muse, mutect2
- MYO1D | c.1133T>C p.V378A | Missense Mutation (SNP) | VAF 18/352 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as COSV59018555; called by muse, mutect2
- MYPN | c.2137C>G p.P713A | Missense Mutation (SNP) | VAF 158/968 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV100589547; called by muse, mutect2
- NLRP8 | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 25/218 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.201); catalogued as rs765907009, COSV99404735; called by muse, mutect2, varscan2
- PPDPFL | c.138G>T p.L46F | Missense Mutation (SNP) | VAF 84/680 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV57461926, COSV57462269; called by muse, mutect2, varscan2
- PTPN14 | c.2803G>A p.E935K | Missense Mutation (SNP) | VAF 176/1060 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as rs1558074769; called by muse, mutect2, varscan2
- PTPRN2 | c.505G>A p.V169M | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs772044419; called by muse, mutect2
- SLC44A2 | c.95C>T p.T32M | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753124039; called by muse, mutect2
- SVEP1 | c.10459G>T p.A3487S | Missense Mutation (SNP) | VAF 22/378 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV52842125; called by muse, mutect2
- TET3 | c.832G>C p.E278Q | Missense Mutation (SNP) | VAF 91/496 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.857); catalogued as COSV59883009; called by muse, mutect2, varscan2
- TRIP12 | c.5033C>T p.A1678V | Missense Mutation (SNP) | VAF 35/312 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs376235388, COSV52259279; called by muse, mutect2, varscan2
- TSHZ3 | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs770463906, COSV99550866; called by muse, mutect2
- ZC3H10 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 32/438 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.549); catalogued as rs1451504618; called by muse, mutect2
- ZYG11A | c.984C>G p.F328L | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.198); catalogued as rs1382775432; called by muse, mutect2, varscan2
- ZYX | c.1031C>T p.S344F | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.687); catalogued as rs1429219941; called by muse, mutect2, varscan2
- ABCA1 | c.3059G>T p.G1020V | Missense Mutation (SNP) | VAF 118/1156 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- ALYREF | c.613G>T p.G205C | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANO3 | c.2866A>T p.M956L | Missense Mutation (SNP) | VAF 65/380 reads (17%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- ATP13A4 | c.31C>G p.L11V | Missense Mutation (SNP) | VAF 470/1347 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ATXN7L2 | c.747G>T p.E249D | Missense Mutation (SNP) | VAF 87/442 reads (20%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BAG1 | c.967G>C p.D323H | Missense Mutation (SNP) | VAF 69/460 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- BEND2 | c.2198A>G p.E733G | Missense Mutation (SNP) | VAF 12/312 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.284); called by muse, mutect2
- CARMIL3 | c.1936G>T p.E646* | Nonsense Mutation (SNP) | VAF 33/474 reads (7%) | called by muse, mutect2
- CCDC73 | c.1724C>T p.S575L | Missense Mutation (SNP) | VAF 38/225 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH6 | c.1996G>C p.E666Q | Missense Mutation (SNP) | VAF 53/934 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDK13 | c.4174C>T p.Q1392* | Nonsense Mutation (SNP) | VAF 33/275 reads (12%) | called by muse, mutect2, varscan2
- CIBAR1 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 39/232 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- CUL7 | c.2711G>C p.R904P | Missense Mutation (SNP) | VAF 100/696 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, varscan2
- DCDC1 | c.741C>G p.F247L | Missense Mutation (SNP) | VAF 52/258 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DDOST | c.406G>A p.D136N (on ENST00000415136; = p.D119N on NM_005216.5) | Missense Mutation (SNP) | VAF 38/320 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- DSCAM | c.4715C>A p.T1572K | Missense Mutation (SNP) | VAF 13/238 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2
- EPHA6 | c.1861A>C p.S621R | Missense Mutation (SNP) | VAF 38/538 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ERCC6L2 | c.1430G>A p.R477K | Missense Mutation (SNP) | VAF 11/320 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.014); called by muse, mutect2
- ERV3-1 | c.1642T>A p.Y548N | Missense Mutation (SNP) | VAF 20/334 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); called by muse, mutect2
- FBXO42 | c.1187G>T p.R396I | Missense Mutation (SNP) | VAF 44/621 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.115); called by muse, mutect2
- FRMPD1 | c.3388A>G p.R1130G | Missense Mutation (SNP) | VAF 45/367 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GALNT4 | c.12G>C p.R4S | Missense Mutation (SNP) | VAF 37/369 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.323); called by muse, mutect2
- GEMIN6 | c.478G>T p.E160* | Nonsense Mutation (SNP) | VAF 19/141 reads (13%) | called by muse, mutect2, varscan2
- GEMIN6 | c.479A>G p.E160G | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.053); called by muse, varscan2
- GIMAP1-GIMAP5 | c.471C>A p.S157R | Missense Mutation (SNP) | VAF 153/767 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- HECTD1 | c.7766C>G p.S2589C | Missense Mutation (SNP) | VAF 50/710 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); called by muse, mutect2
- IFIH1 | c.1537C>G p.L513V | Missense Mutation (SNP) | VAF 73/375 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- IQGAP3 | c.661G>C p.G221R | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- ITGB2 | c.347A>C p.N116T | Missense Mutation (SNP) | VAF 48/805 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2
- KLHDC10 | c.1205T>A p.V402E | Missense Mutation (SNP) | VAF 42/758 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); called by muse, mutect2
- KRTAP5-5 | c.566G>T p.C189F | Missense Mutation (SNP) | VAF 55/409 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- MMRN2 | c.2572G>A p.E858K | Missense Mutation (SNP) | VAF 96/592 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- MRPL24 | c.151G>C p.D51H | Missense Mutation (SNP) | VAF 38/672 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.143); called by muse, mutect2
- MRTFA | c.242-6C>T | Splice Region (SNP) | VAF 36/370 reads (10%) | called by muse, mutect2
- MRTFB | c.1651G>A p.D551N | Missense Mutation (SNP) | VAF 141/864 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- NOBOX | c.1552C>G p.Q518E | Missense Mutation (SNP) | VAF 83/414 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- NTRK2 | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 143/1278 reads (11%) | SIFT tolerated (0.87); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR2T35 | c.583T>C p.Y195H | Missense Mutation (SNP) | VAF 115/955 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- PCDH12 | c.2429C>A p.P810H | Missense Mutation (SNP) | VAF 143/404 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- PCDH12 | c.2428C>A p.P810T | Missense Mutation (SNP) | VAF 145/408 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PPP1R42 | c.58G>C p.E20Q | Missense Mutation (SNP) | VAF 118/639 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- PRKACB | c.689A>G p.Y230C | Missense Mutation (SNP) | VAF 19/397 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- PRKACG | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 33/455 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); called by muse, mutect2
- PSMD11 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 52/988 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.022); called by muse, mutect2
- RPL30 | c.65T>A p.M22K | Missense Mutation (SNP) | VAF 132/614 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- SHQ1 | c.1179C>G p.V393= | Splice Region (SNP) | VAF 82/527 reads (16%) | called by muse, mutect2, varscan2
- TBC1D23 | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 92/267 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- UNCX | c.687C>A p.S229R | Missense Mutation (SNP) | VAF 110/301 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- Z83844.2 | c.797A>G p.D266G | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZBED8 | c.826C>G p.H276D | Missense Mutation (SNP) | VAF 65/517 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ZNF625 | c.785T>C p.L262P | Missense Mutation (SNP) | VAF 58/436 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZNF669 | c.807G>C p.Q269H | Missense Mutation (SNP) | VAF 42/269 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- AASS | c.1017G>T p.V339= | Silent (SNP) | VAF 156/916 reads (17%) | called by muse, mutect2, varscan2
- ARMT1 | c.804C>T p.F268= | Silent (SNP) | VAF 62/442 reads (14%) | called by muse, mutect2, varscan2
- CKAP4 | c.1137G>A p.Q379= | Silent (SNP) | VAF 12/126 reads (10%) | called by muse, mutect2
- CUL7 | c.3030G>C p.L1010= | Silent (SNP) | VAF 56/392 reads (14%) | called by muse, mutect2, varscan2
- ELAVL2 | c.684A>T p.G228= | Silent (SNP) | VAF 39/348 reads (11%) | catalogued as COSV56358117; called by muse, mutect2, varscan2
- ERICH3 | c.4014G>T p.V1338= | Silent (SNP) | VAF 131/755 reads (17%) | called by muse, mutect2, varscan2
- FAF2 | c.876G>A p.Q292= | Silent (SNP) | VAF 9/221 reads (4%) | called by muse, mutect2
- FAM155B | c.300G>A p.P100= | Silent (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- FAM50B | c.258G>A p.R86= | Silent (SNP) | VAF 21/110 reads (19%) | called by muse, mutect2, varscan2
- FAM90A1 | c.627C>T p.D209= | Silent (SNP) | VAF 76/1788 reads (4%) | called by muse, mutect2
- FLNB | c.7566C>G p.L2522= | Silent (SNP) | VAF 52/322 reads (16%) | catalogued as COSV55877530; called by muse, mutect2, varscan2
- FSD1 | c.279C>T p.S93= | Silent (SNP) | VAF 29/218 reads (13%) | called by muse, mutect2, varscan2
- GPR4 | c.960G>A p.S320= | Silent (SNP) | VAF 19/154 reads (12%) | catalogued as rs1372992980; called by muse, mutect2, varscan2
- GSTM5 | c.291G>A p.V97= | Silent (SNP) | VAF 67/485 reads (14%) | called by muse, mutect2, varscan2
- GYG2 | c.936C>T p.C312= | Silent (SNP) | VAF 67/357 reads (19%) | called by muse, mutect2, varscan2
- KCNC2 | c.1308T>A p.T436= | Silent (SNP) | VAF 21/301 reads (7%) | catalogued as COSV54371384; called by muse, mutect2
- MORN3 | c.722G>A p.*241= | Silent (SNP) | VAF 82/367 reads (22%) | called by muse, mutect2, varscan2
- NOP56 | c.255G>A p.P85= | Silent (SNP) | VAF 108/360 reads (30%) | catalogued as rs767263688; called by muse, mutect2, varscan2
- NSMCE2 | c.540G>T p.V180= | Silent (SNP) | VAF 105/835 reads (13%) | called by muse, mutect2, varscan2
- OR4A15 | c.696A>G p.R232= | Silent (SNP) | VAF 72/448 reads (16%) | called by muse, mutect2, varscan2
- PGR | c.583C>T p.L195= | Silent (SNP) | VAF 16/100 reads (16%) | called by muse, mutect2, varscan2
- PPL | c.3156C>T p.V1052= | Silent (SNP) | VAF 51/306 reads (17%) | catalogued as rs780446077; called by muse, mutect2, varscan2
- RAD23B | c.39C>T p.F13= | Silent (SNP) | VAF 45/417 reads (11%) | called by muse, mutect2, varscan2
- RALGAPB | c.4173C>A p.V1391= | Silent (SNP) | VAF 49/266 reads (18%) | called by muse, mutect2, varscan2
- RXYLT1 | c.642C>T p.F214= | Silent (SNP) | VAF 22/312 reads (7%) | called by muse, mutect2
- SDK1 | c.1617G>A p.Q539= | Silent (SNP) | VAF 16/260 reads (6%) | catalogued as rs377274613; called by muse, mutect2
- SLC9A4 | c.2202A>G p.E734= | Silent (SNP) | VAF 54/519 reads (10%) | called by muse, mutect2, varscan2
- ST6GALNAC5 | c.420C>T p.S140= | Silent (SNP) | VAF 26/250 reads (10%) | catalogued as rs748193124; called by muse, mutect2, varscan2
- STAB1 | c.411G>A p.V137= | Silent (SNP) | VAF 20/388 reads (5%) | called by muse, mutect2
- SUN2 | c.447G>A p.Q149= | Silent (SNP) | VAF 83/258 reads (32%) | called by muse, mutect2, varscan2
- SYDE2 | c.168G>A p.R56= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs934970015; called by muse, mutect2, varscan2
- SYNC | c.384A>G p.G128= | Silent (SNP) | VAF 32/505 reads (6%) | catalogued as rs1341702910; called by muse, mutect2
- TRIM49D1 | c.1356C>G p.L452= | Silent (SNP) | VAF 8/80 reads (10%) | called by mutect2, varscan2
- XKRX | c.111C>A p.I37= | Silent (SNP) | VAF 90/515 reads (17%) | called by muse, mutect2, varscan2
- ZFYVE28 | c.567C>T p.Y189= | Silent (SNP) | VAF 33/141 reads (23%) | catalogued as rs185670507; called by muse, mutect2, varscan2
- ABCB8 | c.95+271C>T | Intron (SNP) | VAF 13/108 reads (12%) | catalogued as rs374331390; called by muse, mutect2, varscan2
- BBS2 | c.1528-10C>T | Intron (SNP) | VAF 101/467 reads (22%) | called by muse, mutect2, varscan2
- CDK16 | c.-16G>C | 5'UTR (SNP) | VAF 4/29 reads (14%) | catalogued as rs1334532938; called by muse, mutect2, varscan2
- CHPT1 | c.*115C>G | 3'UTR (SNP) | VAF 40/320 reads (13%) | called by muse, mutect2, varscan2
- CTNNAL1 | c.1835+1667G>A | Intron (SNP) | VAF 43/407 reads (11%) | called by muse, mutect2, varscan2
- DCHS2 | n.6625A>T | RNA (SNP) | VAF 48/323 reads (15%) | called by muse, mutect2, varscan2
- GABPA | c.-122C>T | 5'UTR (SNP) | VAF 24/199 reads (12%) | called by muse, mutect2, varscan2
- GNLY | c.*55G>A | 3'UTR (SNP) | VAF 46/220 reads (21%) | catalogued as rs773987494; called by muse, mutect2, varscan2
- LINC00917 | n.1564+1524G>C | Intron (SNP) | VAF 16/410 reads (4%) | called by muse, mutect2
- MAP4 | c.1999+2715G>C | Intron (SNP) | VAF 88/721 reads (12%) | called by muse, mutect2, varscan2
- METTL8 | chr2:171434747 G>T | 5'Flank (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- MOCS1 | c.-16G>A | 5'UTR (SNP) | VAF 48/407 reads (12%) | called by muse, mutect2, varscan2
- PCOLCE | c.-29G>C | 5'UTR (SNP) | VAF 42/315 reads (13%) | called by muse, mutect2, varscan2
- PKD1L2 | n.2721C>T | RNA (SNP) | VAF 55/250 reads (22%) | catalogued as rs895990710; called by muse, mutect2, varscan2
- SPANXB1 | c.*53G>A | 3'UTR (SNP) | VAF 102/2442 reads (4%) | called by muse, mutect2
- STRA6 | c.*13T>C | 3'UTR (SNP) | VAF 24/73 reads (33%) | catalogued as COSV99997208; called by muse, mutect2, varscan2
- TBX18 | c.292+450del | Intron (DEL) | VAF 51/397 reads (13%) | called by mutect2, pindel, varscan2
- VNN3 | c.*531G>C | 3'UTR (SNP) | VAF 99/532 reads (19%) | called by muse, mutect2, varscan2
- ZNF658B | n.1969C>T | RNA (SNP) | VAF 236/807 reads (29%) | called by muse, mutect2, varscan2
